FM case AD11577 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/6d7da1ff-d717-4c11-9e6f-bcc18fd49af9

Female, 77.1 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the adrenal gland. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
